Surgical pathology report (de-identified scan), TCGA case TCGA-57-1585, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-57-1585-01A (Primary Tumor).

[page 1 of 2]
PHYSICIAN INFORMATION

SURGICAL PATHOLOGY REPORT

DIAGNOSIS

DIAGNOSIS:

A. Omentum:

Extensive infiltration by high-grade, papillary serous adenocarcinoma of ovary.

B. Hysterectomy:

Ovarian carcinoma.

Tumor Characteristics:

1. Histologic type: Papillary serous.
2. Grade: High-grade (grade 3/3).
3. Location: Ovaries.
- a. Ovary involved: Bilateral.
- b. Amount/degree of involvement of each ovary: Tumor partially replaces both ovaries.
4. Lymphovascular space invasion: Present.
5. Right fallopian tube: Not involved by tumor.
6. Left fallopian tube: Serosal involvement by tumor.
7. Omentum involvement by tumor: Present, extremely extensive.
8. Other peritoneal biopsies: None.
Lymph Node Status:
1. Number of lymph nodes examined: None.Other:
1. Cervix: Negative.
2. Endocervix: Serosal involvement by neoplasm.
3. Endometrium: Endometrial polyp.
4. Myometrium: Invasion by neoplasm by direct extension from serosa and lymphovascular space invasion.
5. Uterine serosa: Involved by neoplasm.
6. Other organs or biopsies: None.
7. Correlation with intraoperative findings: None.
8. Results of additional studies: Pending.
9. pTNM stage: T2c (utilizing companion cytology report).

CLINICAL INFORMATION

[page 2 of 2]
CLINICAL INFORMATION

CLINICAL HISTORY:

Preoperative Diagnosis: Ovarian CA?

Postoperative Diagnosis:

Symptoms/Radiologic Findings:

SPECIMENS:

A. Omentum

B. BSO, uterus, cervix

SPECIMEN DATA

GROSS DESCRIPTION:

A. The first container A is labeled with the patient's name _____ omentum. The specimen consists of multiple pieces of yellow-brown hemorrhagic, indurated, yellow-tan, lobular fibroadipose omentum tissue measuring in aggregate 45 x 7 x 2 cm. The omentum is almost completely replaced by yellow-gray fibrotic tissue. Representative sections are submitted in two cassettes labeled _____

B. The second container B is labeled with the patient's name _____ BSO, uterus, cervix. The specimen consists of a uterus with attached cervix and bilateral adnexal complexes. The uterus measures 6.0 x 4.5 x 4.0 cm. and weighs 128 grams. The serosal surface is gray to brown-tan with hemorrhage and adhesions. On the anterior aspect there is attached gray-tan fibrous tissue that displays yellow-gray fibrinous material adhered to the surface. The cervix measures 3.5 cm. in length and 1.5 cm. in diameter and has a 1.0 cm. slit patent os. The ectocervix is light tan with hemorrhage. The endocervical canal is light tan, contains mucus and there is no lesion seen grossly. The endometrial cavity measures 2.5 cm. in length and 0.5 cm. from cornu to cornu. The lining measures 0.1 cm. and is light tan smooth and glistening. There is a pale tan to red-tan polyp measuring 1.5 cm. identified. The myometrium measures up to 0.9 cm. in greatest dimension. On sectioning the cut surface is gray-tan trabecular. There is a white-tan fibrotic area corresponding to the adhered portion of fibrous tissue that measures 1.2 cm. in greatest dimension that grossly appears to be invasion from the tissue through the serosal surface into the myometrium. The left ovary measures 2.5 x 2.0 x 1.0 cm. The surface is brown-tan and shaggy. On sectioning the cut surface is yellow-gray fibrous revealing a probable mass measuring up to 1.2 cm. The left fallopian tube is not grossly identified. There is a possible tubal structure measuring 2.0 cm. in length and 0.5 cm. in diameter with a markedly hemorrhagic cut surface. The right ovary measures 2.5 x 2.0 x 1.5 cm. The surface is gray to brown-tan shaggy. On sectioning there reveals a gray-tan fibrous mass measuring 1.5 cm. in greatest dimension. The right fallopian tube measures 4.5 cm. in length and 0.5 cm. in diameter. On sectioning the fallopian tube is grossly unremarkable. Detached from the specimen and received separately is a yellow-gray shaggy soft tissue mass measuring 4.5 x 3.5 x 2.0 cm. On sectioning it has a gray-tan fibrotic appearance. Representative sections are taken for genomic studies and placed in orange cassettes labeled _____. Received with the specimen are two cassettes, one green and one yellow labeled _____. Representative sections are submitted in cassettes as follows: anterior cervix block 1; posterior cervix block 2; endometrial polyp bisected and submitted in total in blocks 3 and 4; sections from anterior endometrium/myometrium in blocks 5 and 6; posterior endometrium/myometrium in blocks 7 and 8; sections from adhered soft tissue with possible lesion into the myometrium in blocks 9 and 10; sections from left ovary in blocks 11-13; possible left fallopian tube in block 14; sections from right ovarian mass in blocks 15-17; right fallopian tube block 18; separately submitted mass in blocks 19-22.

Source: NCI Genomic Data Commons file 9b1a32e4-7e3f-4f6b-83c5-6a967e6edce0 (TCGA-57-1585.2C748ACA-E5B2-4418-9820-1343293D379F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).